Somatic mutation profile of tumor specimen TCGA-C5-A7XC-01A (aliquot TCGA-C5-A7XC-01A-11D-A387-09) from TCGA case TCGA-C5-A7XC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 26.8 years (9,776 days).
Specimen TCGA-C5-A7XC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82ba52c4-cacb-4368-adf8-967f140b2ac2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A7XC-10A (Blood Derived Normal), aliquot TCGA-C5-A7XC-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b0f77bc-87a1-4cac-93cf-8c444d548f01

The open-access MAF lists 70 somatic variants for this specimen: 50 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 19, Nonsense Mutation 3, Splice Site 3, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB7 | c.1937C>T p.T646I (on ENST00000373394 / NM_001271696.3; = p.T647I on NM_004299.6) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV53724467, COSV99504466; called by muse, mutect2
- ACACB | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1406432298, COSV100623010; called by muse, mutect2, varscan2
- ADCY4 | c.2049C>G p.F683L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs763475799, COSV100156634, COSV104406598; called by muse, mutect2, varscan2
- ANO8 | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV50202364, COSV99344576; called by muse, mutect2, varscan2
- C4orf17 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV58511837; called by muse, mutect2, varscan2
- CDHR1 | c.2506G>A p.V836I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV100258985; called by muse, mutect2
- CEMIP | c.2713G>T p.A905S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV99586535, COSV99586848; called by muse, mutect2, varscan2
- CENPE | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99478213; called by muse, mutect2
- CPSF3 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.488); catalogued as COSV99432902; called by muse, mutect2, varscan2
- CPXM2 | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs750948954, COSV53860220; called by muse, mutect2, varscan2
- DOCK10 | c.2930C>G p.S977* | Nonsense Mutation (SNP) | VAF 7/84 reads (8%) | catalogued as COSV99288047, COSV99289946; called by muse, mutect2
- FAM120C | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV100070176; called by muse, mutect2
- FBLN2 | c.2909G>C p.G970A | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99852074; called by muse, mutect2, varscan2
- FBXW7 | c.1678G>C p.D560H (on ENST00000281708 / NM_001349798.2; = p.D480H on NM_018315.5) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55893275, COSV55929570; called by muse, mutect2, varscan2
- FGD1 | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs749593888, COSV100911122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FSCB | c.2192T>C p.I731T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs373016481; called by muse, mutect2, varscan2
- H6PD | c.1533G>C p.L511F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101072493; called by muse, mutect2
- IGSF10 | c.6300C>G p.N2100K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.245); catalogued as COSV99180793; called by muse, mutect2, varscan2
- ITCH | c.607C>A p.Q203K (on ENST00000262650 / NM_001257137.3; = p.Q162K on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV99392665; called by muse, mutect2
- LEMD1 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100903467, COSV65672038; called by muse, mutect2
- MAN2A2 | c.535+1G>T p.X179_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100847896; called by muse, mutect2, varscan2
- MUC16 | c.18083C>T p.S6028F | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101200181; called by muse, mutect2
- MYOM3 | c.2176C>A p.R726S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.094); catalogued as rs369571711, COSV58398420; called by muse, mutect2, varscan2
- PACS1 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100270179; called by muse, mutect2, varscan2
- PDCD6 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs370878298; called by muse, mutect2, varscan2
- PEX5 | c.1714C>T p.H572Y (on ENST00000420616; = p.H564Y on NM_000319.5) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.138); catalogued as COSV99871029; called by muse, mutect2, varscan2
- PRKCE | c.2014G>C p.D672H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs891028429, COSV100078317; called by muse, mutect2
- PSMD2 | c.2037G>A p.L679= | Splice Region (SNP) | VAF 9/56 reads (16%) | catalogued as rs1197580389, COSV100031831; called by muse, mutect2, varscan2
- RAB39B | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV101035001; called by muse, mutect2
- RPAP1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs964370076, COSV100427176, COSV100427413; called by muse, mutect2, varscan2
- RPP25 | c.382G>C p.V128L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV100446223, COSV100446236; called by muse, mutect2, varscan2
- RS1 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.012); catalogued as rs1279917353, COSV101183820; called by muse, mutect2, varscan2
- SI | c.1146+1G>T p.X382_splice | Splice Site (SNP) | VAF 22/124 reads (18%) | catalogued as COSV100015907; called by muse, mutect2
- SLF2 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV53280063, COSV99489333; called by muse, mutect2
- SLFN13 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV99540073; called by muse, mutect2
- SP6 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60619173; called by muse, mutect2, varscan2
- STAB1 | c.5899G>A p.E1967K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV100195103; called by muse, mutect2, varscan2
- STAT6 | c.2059G>T p.D687Y | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV100272701; called by muse, mutect2, varscan2
- TEK | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV66231598; called by muse, mutect2
- TLR4 | c.239T>C p.L80P (on ENST00000355622 / NM_138554.5; = p.L40P on NM_003266.4) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100790660; called by muse, mutect2, varscan2
- TPCN1 | c.2246G>A p.R749K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100136802, COSV59234882; called by muse, mutect2, varscan2
- TPP2 | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101060307; called by muse, mutect2, varscan2
- TTN | c.50017G>A p.E16673K (on ENST00000591111; = p.E9249K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | PolyPhen probably damaging (0.994); catalogued as COSV100617611; called by muse, mutect2, varscan2
- UBE3A | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV51667449; called by muse, mutect2
- WNK2 | c.1679G>T p.S560I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV99942996; called by mutect2, varscan2
- ZFAND5 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as COSV52988291, COSV99428532; called by muse, mutect2, varscan2
- ZNF43 | c.1685G>C p.G562A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100731842; called by muse, mutect2, varscan2
- DIDO1 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | called by muse, varscan2
- MAP7D2 | c.1684-1G>A p.X562_splice | Splice Site (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- TRUB2 | c.338G>A p.C113Y | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.226); called by muse, varscan2
- ATP7B | c.3462G>A p.L1154= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs767069278, COSV99666557; called by muse, mutect2, varscan2
- BANP | c.306C>T p.L102= (on ENST00000286122; = p.L110= on NM_017869.4) | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as rs374004218; called by muse, mutect2
- DAPK1 | c.2952G>A p.Q984= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100802063; called by muse, mutect2, varscan2
- DNAH3 | c.4395G>A p.G1465= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99768131; called by muse, mutect2, varscan2
- ERCC2 | c.849C>T p.D283= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV99676354; called by muse, mutect2, varscan2
- HSPG2 | c.7377C>T p.L2459= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs148384253, COSV65972995; called by muse, mutect2, varscan2
- NPHS1 | c.2208G>A p.V736= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs988385367, COSV100799953; called by muse, mutect2, varscan2
- ORAI2 | c.438C>T p.I146= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1324354244, COSV62689977; called by muse, mutect2
- OTOF | c.1128C>T p.D376= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs745434989, COSV99064334, COSV99717212; called by muse, mutect2, varscan2
- PLG | c.300C>G p.L100= | Silent (SNP) | VAF 57/155 reads (37%) | catalogued as COSV99804776; called by muse, mutect2, varscan2
- RPGRIP1 | c.3462G>A p.S1154= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs772065227, COSV52846420; called by muse, mutect2, varscan2
- SELENOO | c.735G>A p.L245= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV101096870; called by muse, mutect2, varscan2
- TDRD7 | c.1758C>T p.S586= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs751761643, COSV100795619; called by muse, varscan2
- TGFB3 | c.465G>A p.R155= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99472574; called by muse, varscan2
- TICRR | c.4767C>T p.L1589= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99176647; called by muse, mutect2, varscan2
- TRMT6 | c.84G>A p.L28= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV52544728; called by muse, mutect2
- UBC | c.378G>A p.L126= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV100299017; called by muse, mutect2, varscan2
- UTRN | c.3330C>T p.S1110= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1313837443, COSV100839987; called by muse, mutect2, varscan2
- VPS53 | c.1740T>C p.S580= (on ENST00000571805 / NM_001366253.2; = p.S551= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV52128527; called by muse, mutect2, varscan2
- POLE | c.6658-284G>A | Intron (SNP) | VAF 17/54 reads (31%) | catalogued as rs779132980, COSV57677347; called by muse, mutect2, varscan2
